Somatic mutation profile of tumor specimen TARGET-10-PAUBXP-09A (aliquot TARGET-10-PAUBXP-09A-01D) from TARGET case TARGET-10-PAUBXP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,035 days).
Specimen TARGET-10-PAUBXP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7132e0ca-801c-4b59-a2bf-a46ac31a0ece.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUBXP-10A (Blood Derived Normal), aliquot TARGET-10-PAUBXP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2081de4b-93b0-49de-bdff-7ffba99bee93

The open-access MAF lists 23 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 7, Silent 3, In Frame Ins 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 43/90 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C6orf118 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs753247816, COSV57812383; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, mutect2, varscan2
- PLLP | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757490812, COSV54657649; called by muse, mutect2, varscan2
- PRKDC | c.6401G>A p.G2134E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV58042107; called by muse, mutect2, varscan2
- RHOU | c.391_392insGCCCTTTGTTGCCCT p.V131delinsGPLLPL | In Frame Ins (INS) | VAF 11/32 reads (34%) | catalogued as COSV64208244; called by mutect2, pindel, varscan2
- SEMA3F | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99137318; called by muse, mutect2, varscan2
- SLC35G2 | c.819A>G p.I273M | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV67587759; called by muse, mutect2, varscan2
- UBLCP1 | c.296T>A p.F99Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV57142529; called by muse, mutect2, varscan2
- ZNF138 | c.845A>G p.E282G (on ENST00000307355 / NM_001367572.1; = p.E256G on NM_006524.4) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV56463566; called by muse, mutect2, varscan2
- TRBJ2-3 | chr7:142796845 del TGA | Missense Mutation (DEL) | VAF 16/16 reads (100%) | called by mutect2, varscan2
- SH3YL1 | c.210G>A p.A70= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs1056413860; called by muse, mutect2, varscan2
- SYK | c.1044C>T p.Y348= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs142936514, COSV65325088; called by muse, mutect2, varscan2
- TEX15 | c.7098C>T p.S2366= (on ENST00000256246; = p.S2749= on NM_001350162.2) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs772422409, COSV56341688, COSV56343652; called by muse, mutect2, varscan2
- CCDC40 | c.2832+380C>T | Intron (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- HBB | c.-26T>C | 5'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- INPP4B | c.372+18869C>T | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2
- MROH2B | c.1501+51T>C | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- STAP2 | c.661-11T>A | Intron (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- TAF8 | chr6:42048501 C>T | 5'Flank (SNP) | VAF 45/105 reads (43%) | catalogued as COSV65895621; called by muse, mutect2, varscan2
- THOC5 | c.966+59_966+77delinsAGGT | Intron (DEL) | VAF 27/74 reads (36%) | called by pindel, varscan2*
- TSGA13 | c.659-50_659-49insGGG | Intron (INS) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- XKR4 | c.806+36910C>T | Intron (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
